Somatic mutation profile of tumor specimen C3N-03204-01 (aliquot CPT0209490006) from CPTAC case C3N-03204, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA3; Tumor grade: G2; Age at diagnosis: 62.0 years (22,652 days).
Specimen C3N-03204-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d437239c-d773-4df1-81b8-27494e4e4177.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03204-31 (Blood Derived Normal), aliquot CPT0209550002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a73f61ea-6191-48cd-8082-f3f3f074ac6c

The open-access MAF lists 412 somatic variants for this specimen: 287 protein-altering or splice-affecting, 76 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 240, Silent 76, Nonsense Mutation 26, Intron 20, RNA 14, Frame Shift Del 10, Splice Site 7, 5'UTR 6, 3'UTR 5, Splice Region 4, 3'Flank 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH9 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 134/376 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913657, CM022045; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD11 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 211/664 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.076); catalogued as rs782689770; called by muse, mutect2, varscan2
- ACTR5 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.112); catalogued as COSV54759973; called by muse, mutect2, varscan2
- AMDHD2 | c.1142-5C>T | Splice Region (SNP) | VAF 96/189 reads (51%) | catalogued as rs751672581; called by muse, mutect2, varscan2
- APBA1 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 80/145 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); catalogued as rs776047651; called by muse, mutect2, varscan2
- ARHGEF1 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 22/626 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.166); catalogued as rs139162951; called by muse, mutect2
- ATP4A | c.12C>T p.A4= | Splice Region (SNP) | VAF 49/235 reads (21%) | catalogued as rs143227044; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2084C>T p.S695F | Missense Mutation (SNP) | VAF 146/656 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as COSV59478954; called by muse, mutect2
- B3GNT3 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 118/231 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs776135956; called by muse, mutect2, varscan2
- B4GALT2 | c.32G>C p.R11P | Missense Mutation (SNP) | VAF 162/450 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs536172060, COSV52543955; called by muse, mutect2, varscan2
- BCHE | c.1286C>A p.P429H | Missense Mutation (SNP) | VAF 71/229 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100013010, COSV52262937; called by muse, mutect2, varscan2
- BLOC1S4 | c.284G>C p.R95T | Missense Mutation (SNP) | VAF 158/328 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs1049362192; called by muse, mutect2, varscan2
- BTN1A1 | c.746C>G p.A249G | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as COSV55067531, COSV99764081; called by muse, mutect2, varscan2
- CCDC141 | c.1963A>T p.N655Y | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs1302927922, COSV55381005; called by muse, mutect2, varscan2
- CDH23 | c.8279C>G p.P2760R | Missense Mutation (SNP) | VAF 119/431 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.164); catalogued as rs1174417978; called by muse, mutect2, varscan2
- CHST3 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 86/273 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs1294596678; called by muse, mutect2, varscan2
- CNNM2 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 229/743 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV63995826; called by muse, mutect2, varscan2
- COL11A1 | c.96G>T p.E32D | Missense Mutation (SNP) | VAF 140/338 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as COSV100615800; called by muse, mutect2, varscan2
- COL5A2 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 112/361 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs146005731, COSV66409887; called by muse, mutect2, varscan2
- CSMD1 | c.7870G>T p.G2624* (on ENST00000520002; = p.G2623* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 46/86 reads (53%) | catalogued as COSV100148927; called by muse, mutect2, varscan2
- CYP27B1 | c.1294C>A p.R432S | Missense Mutation (SNP) | VAF 108/295 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM126950, CM1514216, COSV99141676; called by muse, mutect2, varscan2
- CYP4X1 | c.1297C>T p.Q433* | Nonsense Mutation (SNP) | VAF 62/228 reads (27%) | catalogued as rs1335936100, COSV64149501, COSV64149596; called by muse, mutect2, varscan2
- DOCK3 | c.3099G>C p.W1033C | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56515164; called by muse, mutect2, varscan2
- DPP4 | c.2269C>T p.H757Y | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV62109014; called by muse, mutect2, varscan2
- FAM120AOS | c.568del p.L190Sfs*37 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | catalogued as COSV52907115; called by mutect2, pindel, varscan2
- FAM171B | c.2371G>A p.A791T | Missense Mutation (SNP) | VAF 52/268 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.192); catalogued as rs141004508; called by muse, mutect2, varscan2
- FAM47A | c.1538G>T p.R513L | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.63); PolyPhen benign (0.378); catalogued as COSV60498140; called by muse, varscan2
- FBXL19 | c.1583C>T p.S528L | Missense Mutation (SNP) | VAF 109/222 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV100609356; called by muse, mutect2, varscan2
- FBXO31 | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 53/302 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as rs1051837697; called by muse, mutect2, varscan2
- FMN2 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV100142119; called by muse, mutect2, varscan2
- FRMD1 | c.1433G>A p.S478N | Missense Mutation (SNP) | VAF 137/418 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.635); catalogued as rs770077391; called by muse, mutect2, varscan2
- GBX2 | c.948G>T p.E316D | Missense Mutation (SNP) | VAF 138/456 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV60445056; called by muse, mutect2, varscan2
- GIMAP6 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 112/338 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV61033425, COSV61034772; called by muse, mutect2, varscan2
- GPR39 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 136/379 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375756316; called by muse, mutect2, varscan2
- GRIK4 | c.866G>T p.W289L | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV101483598; called by muse, mutect2, varscan2
- HIVEP1 | c.6004C>G p.Q2002E | Missense Mutation (SNP) | VAF 68/123 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as rs770700024; called by muse, mutect2, varscan2
- HSPB3 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 492/1028 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs371683736, COSV57356612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGF1R | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 247/473 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV51396462; called by muse, mutect2, varscan2
- KCNG3 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1291945605; called by muse, mutect2, varscan2
- KCNT1 | c.2196G>T p.K732N (on ENST00000488444; = p.K751N on NM_020822.3) | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV99704845; called by muse, mutect2, varscan2
- KDM5C | c.4513G>A p.E1505K | Missense Mutation (SNP) | VAF 68/94 reads (72%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.099); catalogued as COSV64771549; called by muse, mutect2, varscan2
- KEAP1 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV50633233; called by muse, mutect2, varscan2
- KIAA0895L | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as rs775929211; called by mutect2, varscan2
- KIF13B | c.4748G>T p.G1583V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs1464964973; called by muse, mutect2
- KMT2D | c.15010G>T p.E5004* | Nonsense Mutation (SNP) | VAF 207/705 reads (29%) | catalogued as COSV56452161; called by muse, mutect2, varscan2
- KRT31 | c.604C>A p.R202S | Missense Mutation (SNP) | VAF 107/150 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as rs764580873, COSV52435510; called by muse, mutect2, varscan2
- LAMA5 | c.4292A>G p.Y1431C | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1568933572; called by muse, mutect2, varscan2
- LIG4 | c.2029G>C p.D677H | Missense Mutation (SNP) | VAF 78/265 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV63597235; called by muse, mutect2, varscan2
- LMNTD1 | c.703T>C p.C235R | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286507035; called by muse, mutect2, varscan2
- LRP1B | c.4381G>C p.E1461Q | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV67196692, COSV67227313; called by muse, mutect2, varscan2
- LRRTM4 | c.449C>G p.S150C | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs771505210; called by muse, mutect2, varscan2
- MGAM2 | c.5725A>G p.I1909V | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated, low confidence (1); catalogued as rs1321705112; called by muse, mutect2, varscan2
- MIB2 | c.3184A>G p.I1062V | Missense Mutation (SNP) | VAF 101/194 reads (52%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as rs1454086665; called by muse, mutect2, varscan2
- MS4A15 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 149/463 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs758672100; called by muse, mutect2, varscan2
- MYH9 | c.1536C>G p.I512M | Missense Mutation (SNP) | VAF 238/785 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV53385738; called by muse, mutect2
- NCAM2 | c.703T>A p.S235T | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV53106198; called by muse, mutect2, varscan2
- NEBL | c.842C>G p.S281* | Nonsense Mutation (SNP) | VAF 112/374 reads (30%) | catalogued as COSV65805539; called by muse, mutect2, varscan2
- NRK | c.1169C>G p.S390C | Missense Mutation (SNP) | VAF 40/59 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs1296217655; called by muse, mutect2, varscan2
- OR10G8 | c.495del p.L165Ffs*20 | Frame Shift Del (DEL) | VAF 90/367 reads (25%) | catalogued as COSV101461873; called by mutect2, pindel, varscan2
- OR8S1 | c.1039G>T p.A347S | Missense Mutation (SNP) | VAF 86/244 reads (35%) | PolyPhen possibly damaging (0.515); catalogued as COSV59599944; called by muse, mutect2, varscan2
- PCDHA11 | c.401C>G p.S134W | Missense Mutation (SNP) | VAF 172/316 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); catalogued as rs959374162; called by muse, mutect2, varscan2
- PCDHA11 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 413/756 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs376574285; called by muse, mutect2, varscan2
- PDE8B | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 164/321 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1441711806, COSV53731521; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCB1 | c.593G>T p.R198M | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV62047085; called by muse, mutect2, varscan2
- PODXL2 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV61064484; called by muse, mutect2, varscan2
- POLR1D | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 88/192 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV68799526, COSV68799985; called by muse, mutect2, varscan2
- PPP1R2C | c.515C>A p.T172K | Missense Mutation (SNP) | VAF 120/195 reads (62%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV65364096; called by muse, mutect2, varscan2
- PRDM1 | c.1716G>C p.K572N | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100958652, COSV64846498; called by muse, mutect2, varscan2
- PRDM9 | c.1300G>T p.D434Y | Missense Mutation (SNP) | VAF 742/1586 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.184); catalogued as COSV57012182, COSV57015325, COSV99689899; called by mutect2, varscan2
- PRPF38B | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100898342; called by muse, mutect2, varscan2
- PRRC2A | c.5387C>A p.S1796* | Nonsense Mutation (SNP) | VAF 55/148 reads (37%) | catalogued as COSV52994148; called by muse, mutect2, varscan2
- PSIP1 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 52/102 reads (51%) | catalogued as COSV101051010; called by muse, varscan2
- RBM4B | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 142/485 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs912606424, COSV100026467; called by muse, mutect2, varscan2
- RNF148 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 133/492 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs1328338406; called by muse, mutect2, varscan2
- SEZ6L | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 91/313 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759752155, COSV50660793; called by muse, mutect2, varscan2
- SHISA7 | c.1076del p.G359Afs*178 | Frame Shift Del (DEL) | VAF 128/325 reads (39%) | catalogued as rs1568449946; called by mutect2, pindel, varscan2
- SLC17A1 | c.634G>T p.V212L | Missense Mutation (SNP) | VAF 99/244 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs368681960; called by muse, mutect2, varscan2
- SLCO1A2 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 14/109 reads (13%) | catalogued as COSV56601007, COSV56602235; called by muse, mutect2, varscan2
- SMC4 | c.1086G>C p.M362I | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV61007373; called by muse, mutect2, varscan2
- SPHKAP | c.2714G>T p.G905V | Missense Mutation (SNP) | VAF 70/294 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV60870362; called by muse, mutect2, varscan2
- SRCAP | c.8864C>G p.S2955C | Missense Mutation (SNP) | VAF 78/282 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); catalogued as COSV52679134; called by muse, mutect2, varscan2
- STAB2 | c.1327A>G p.M443V | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs775105430; called by muse, mutect2, varscan2
- STOX1 | c.1275G>T p.Q425H | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV53815501; called by muse, mutect2, varscan2
- SUPV3L1 | c.1187A>G p.Y396C | Missense Mutation (SNP) | VAF 85/319 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361326027; called by muse, mutect2, varscan2
- TAAR1 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51587762, COSV51589335; called by muse, mutect2, varscan2
- TAF2 | c.721C>G p.P241A | Missense Mutation (SNP) | VAF 101/317 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65417638; called by muse, mutect2, varscan2
- TAOK3 | c.1547T>C p.V516A | Missense Mutation (SNP) | VAF 106/280 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs776458931; called by muse, mutect2, varscan2
- TGM6 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 236/782 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs371408722; called by muse, varscan2
- TIMM44 | c.977A>G p.N326S | Missense Mutation (SNP) | VAF 105/192 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs773663594; called by muse, mutect2, varscan2
- TJP3 | c.1880T>C p.V627A | Missense Mutation (SNP) | VAF 116/244 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs757517731; called by muse, mutect2, varscan2
- TMEM182 | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 124/378 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV68425500; called by muse, mutect2, varscan2
- TMEM200C | c.1622G>C p.R541P | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs761961772; called by muse, mutect2, varscan2
- TP53 | c.173del p.P58Qfs*65 | Frame Shift Del (DEL) | VAF 206/412 reads (50%) | catalogued as COSV52675650, COSV53041942, COSV53097051; called by mutect2, pindel, varscan2
- TRPC6 | c.1561T>C p.Y521H | Missense Mutation (SNP) | VAF 118/374 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100723489; called by muse, mutect2, varscan2
- TTN | c.7727C>A p.S2576Y (on ENST00000591111; = p.S2530Y on NM_003319.4) | Missense Mutation (SNP) | VAF 39/151 reads (26%) | PolyPhen benign (0.342); catalogued as rs1420811529; called by muse, mutect2, varscan2
- ULK1 | c.1769C>A p.P590H | Missense Mutation (SNP) | VAF 193/554 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs1179295412; called by muse, mutect2, varscan2
- UNC5B | c.2159C>T p.T720M | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1487764172; called by muse, mutect2, varscan2
- USP15 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99740120; called by muse, mutect2, varscan2
- VNN1 | c.1160A>G p.H387R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs150060408; called by muse, mutect2, varscan2
- VWA5B2 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 334/597 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.249); catalogued as rs1261361770; called by muse, mutect2, varscan2
- XIRP2 | c.3950G>A p.W1317* (on ENST00000628543; = p.W1492* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 42/101 reads (42%) | catalogued as rs1292589694; called by muse, mutect2, varscan2
- ZAN | c.2254C>G p.P752A | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.42); catalogued as rs781286626; called by muse, mutect2, varscan2
- ZBTB38 | c.1586A>G p.Y529C | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560855672; called by muse, mutect2, varscan2
- ZC3H13 | c.1207C>G p.H403D | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.107); catalogued as COSV54457704; called by muse, mutect2
- ZFHX4 | c.6803G>T p.R2268L | Missense Mutation (SNP) | VAF 73/243 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50479112; called by muse, mutect2, varscan2
- ZIC4 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV67173302; called by muse, mutect2
- ZNF154 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs369809366; called by muse, mutect2, varscan2
- ABCA13 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCC9 | c.4350C>G p.S1450R | Missense Mutation (SNP) | VAF 386/699 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRL1 | c.3533G>T p.R1178L (on ENST00000340736 / NM_001008701.3; = p.R1173L on NM_014921.5) | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- AEBP2 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 104/453 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- ALDH6A1 | c.815G>C p.R272T | Missense Mutation (SNP) | VAF 138/291 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ANKRD20A5P | n.203+2del | Splice Site (DEL) | VAF 38/190 reads (20%) | called by pindel, varscan2
- ANKRD27 | c.1308C>G p.F436L | Missense Mutation (SNP) | VAF 113/219 reads (52%) | SIFT tolerated (0.65); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ANKRD60 | c.938A>G p.K313R | Missense Mutation (SNP) | VAF 109/369 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- APBB1IP | c.1655A>T p.D552V | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ARAP2 | c.1974-1G>A p.X658_splice | Splice Site (SNP) | VAF 46/79 reads (58%) | called by muse, mutect2, varscan2
- ARHGAP10 | c.1868-2A>C p.X623_splice | Splice Site (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- ARHGAP10 | c.1868-1G>T p.X623_splice | Splice Site (SNP) | VAF 42/94 reads (45%) | called by mutect2, varscan2
- ARHGEF25 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- ASB15 | c.50T>C p.I17T | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- ATG2A | c.26C>G p.S9* | Nonsense Mutation (SNP) | VAF 87/216 reads (40%) | called by muse, mutect2, varscan2
- ATP1B3 | c.742G>T p.V248F | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ATP6V0A4 | c.2086G>T p.G696C | Missense Mutation (SNP) | VAF 144/661 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- ATP6V1B1 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 171/342 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BAHCC1 | c.6894G>T p.M2298I | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- BMPR1A | c.838A>G p.T280A | Missense Mutation (SNP) | VAF 135/435 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- BTD | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 145/315 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BZW2 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- C16orf78 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C2CD6 | c.337C>G p.H113D | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CACNA2D2 | c.2326G>A p.E776K (on ENST00000479441 / NM_001174051.3; = p.E769K on NM_006030.4) | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- CACNG3 | c.77T>C p.I26T | Missense Mutation (SNP) | VAF 11/338 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CADM4 | c.64+1G>A p.X22_splice | Splice Site (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2
- CAPN9 | c.1136A>C p.Q379P | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CARNMT1 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 292/578 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, varscan2
- CCDC146 | c.190A>G p.M64V | Missense Mutation (SNP) | VAF 89/266 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC168 | c.11242G>T p.G3748* | Nonsense Mutation (SNP) | VAF 57/244 reads (23%) | called by muse, mutect2, varscan2
- CDON | c.3306G>C p.Q1102H | Missense Mutation (SNP) | VAF 197/533 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- CETN1 | c.89A>T p.K30M | Missense Mutation (SNP) | VAF 99/297 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- CFAP99 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 107/202 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHEK2 | c.371C>A p.S124Y | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CHRD | c.2396G>T p.W799L | Missense Mutation (SNP) | VAF 171/340 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CNTN4 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 119/264 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- COL22A1 | c.3888G>T p.M1296I | Missense Mutation (SNP) | VAF 79/253 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL4A3 | c.4331G>A p.R1444K | Missense Mutation (SNP) | VAF 35/631 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.028); called by muse, mutect2
- CORO7-PAM16 | c.2915C>T p.S972F | Missense Mutation (SNP) | VAF 124/242 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CPED1 | c.565C>A p.Q189K | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CSKMT | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CSMD2 | c.2798G>T p.G933V | Missense Mutation (SNP) | VAF 100/377 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCDC1 | c.3587A>G p.E1196G (on ENST00000597505 / NM_001367979.1; = p.E303G on NM_020869.3) | Missense Mutation (SNP) | VAF 191/789 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- DNAH7 | c.3395C>A p.S1132* | Nonsense Mutation (SNP) | VAF 66/225 reads (29%) | called by muse, mutect2, varscan2
- DNHD1 | c.8388G>C p.Q2796H | Missense Mutation (SNP) | VAF 100/214 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK4 | c.3051G>T p.Q1017H | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DYNC2H1 | c.12589A>T p.S4197C | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- EYS | c.5960C>A p.T1987N | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- F5 | c.6285C>A p.Y2095* | Nonsense Mutation (SNP) | VAF 193/520 reads (37%) | called by muse, mutect2, varscan2
- FAM186A | c.6656G>C p.R2219P | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM47A | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 60/91 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- FCSK | c.425C>A p.S142Y | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); called by muse, mutect2
- FRMPD2 | c.1912A>C p.N638H | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- G2E3 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- G2E3 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2
- G2E3 | c.1440A>T p.E480D | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.67); called by muse, mutect2
- GBP7 | c.465A>C p.K155N | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- GCGR | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 377/602 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- GLI2 | c.3077G>C p.G1026A (on ENST00000361492 / NM_001374353.1; = p.G1043A on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GMEB1 | c.129-2A>T p.X43_splice | Splice Site (SNP) | VAF 48/135 reads (36%) | called by muse, mutect2, varscan2
- GRIN3B | c.1803C>A p.Y601* | Nonsense Mutation (SNP) | VAF 181/368 reads (49%) | called by muse, mutect2, varscan2
- GRK3 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 72/218 reads (33%) | called by muse, mutect2, varscan2
- GZF1 | c.1575C>G p.F525L | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HMX3 | c.477G>T p.K159N | Missense Mutation (SNP) | VAF 125/353 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- IMPG1 | c.809T>A p.M270K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- IPO13 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 100/456 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- KALRN | c.8108A>G p.H2703R (on ENST00000360013 / NM_001024660.4; = p.H1006R on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- KAT6A | c.3716G>T p.G1239V | Missense Mutation (SNP) | VAF 160/506 reads (32%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KAT6B | c.4739A>G p.Q1580R | Missense Mutation (SNP) | VAF 172/507 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- KCND2 | c.1346G>T p.R449L | Missense Mutation (SNP) | VAF 153/497 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- KCNH7 | c.1128+2T>A p.X376_splice | Splice Site (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- KEAP1 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 23/291 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- KIAA0586 | c.506C>G p.A169G (on ENST00000619416 / NM_001244190.2; = p.A184G on NM_014749.5) | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIF21A | c.1000G>T p.D334Y | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT79 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 110/414 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- LONRF2 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LRBA | c.6917C>G p.S2306* | Nonsense Mutation (SNP) | VAF 46/76 reads (61%) | called by muse, mutect2, varscan2
- LYST | c.10544T>G p.M3515R | Missense Mutation (SNP) | VAF 93/193 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MAGED1 | c.1659G>T p.T553= | Splice Region (SNP) | VAF 81/113 reads (72%) | called by muse, mutect2, varscan2
- MAP3K21 | c.1994C>G p.P665R | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- MCUB | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- METTL22 | c.118A>G p.S40G | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP16 | c.589T>G p.S197A | Missense Mutation (SNP) | VAF 100/338 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- MMP20 | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 22/750 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MPEG1 | c.506C>A p.S169* | Nonsense Mutation (SNP) | VAF 116/338 reads (34%) | called by muse, mutect2, varscan2
- MPP6 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- MRC1 | c.1082A>T p.H361L | Missense Mutation (SNP) | VAF 131/442 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2
- MUC15 | c.452G>T p.W151L | Missense Mutation (SNP) | VAF 111/220 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC6 | c.5571C>G p.I1857M | Missense Mutation (SNP) | VAF 151/798 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- MYO16 | c.4872del p.V1625Wfs*16 | Frame Shift Del (DEL) | VAF 58/168 reads (35%) | called by mutect2, pindel, varscan2
- MYO1F | c.195C>A p.Y65* | Nonsense Mutation (SNP) | VAF 179/362 reads (49%) | called by muse, mutect2, varscan2
- NCAM2 | c.855T>G p.N285K | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- NEB | c.9776G>A p.R3259K | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- NELFE | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- NFRKB | c.3061G>C p.D1021H (on ENST00000446488 / NM_001143835.2; = p.D1046H on NM_006165.3) | Missense Mutation (SNP) | VAF 159/468 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- NOMO1 | c.607A>T p.N203Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by mutect2, varscan2
- NPIPB13 | c.273C>G p.F91L | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); called by mutect2, varscan2
- OLFML1 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T2 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 135/536 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OR4N2 | c.896A>G p.K299R | Missense Mutation (SNP) | VAF 64/263 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4Q2 | c.859C>A p.L287I | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PCDH11X | c.1053T>A p.N351K | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE3A | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 58/344 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PDIA4 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDZD2 | c.2792G>T p.G931V | Missense Mutation (SNP) | VAF 139/365 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PGAP1 | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIP4K2A | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | called by muse, varscan2
- PIWIL4 | c.1531_1537del p.G511Wfs*11 | Frame Shift Del (DEL) | VAF 53/178 reads (30%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.6550T>G p.F2184V | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PLEKHG2 | c.3450A>T p.Q1150H | Missense Mutation (SNP) | VAF 135/583 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- PLVAP | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLR3E | c.121G>C p.D41H | Missense Mutation (SNP) | VAF 93/205 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- PRR36 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 103/215 reads (48%) | SIFT tolerated, low confidence (0.07); called by muse, mutect2, varscan2
- PRTG | c.55C>G p.R19G | Missense Mutation (SNP) | VAF 153/291 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRK | c.1001C>G p.S334* | Nonsense Mutation (SNP) | VAF 135/441 reads (31%) | called by muse, mutect2, varscan2
- PURG | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- QSER1 | c.1190A>G p.N397S (on ENST00000399302; = p.N526S on NM_001076786.3) | Missense Mutation (SNP) | VAF 94/189 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM33 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.647); called by muse, varscan2
- REC114 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 107/200 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RELN | c.1713G>C p.M571I | Missense Mutation (SNP) | VAF 121/369 reads (33%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- RGSL1 | c.964A>T p.N322Y | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- RICTOR | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- RINT1 | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 31/139 reads (22%) | called by muse, mutect2, varscan2
- RNASE11 | c.242T>C p.L81S | Missense Mutation (SNP) | VAF 72/286 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- RNASEL | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROM1 | c.910G>C p.G304R | Missense Mutation (SNP) | VAF 261/802 reads (33%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- RPS2 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RPUSD4 | c.892del p.Q298Rfs*8 | Frame Shift Del (DEL) | VAF 78/281 reads (28%) | called by mutect2, pindel, varscan2
- RRP15 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 86/285 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RYR2 | c.3553G>A p.D1185N | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- S100A5 | c.51C>A p.H17Q | Missense Mutation (SNP) | VAF 105/372 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- SETBP1 | c.489C>G p.L163= | Splice Region (SNP) | VAF 136/324 reads (42%) | called by muse, mutect2, varscan2
- SLC12A6 | c.2231G>C p.R744P (on ENST00000354181 / NM_001365088.1; = p.R693P on NM_005135.2) | Missense Mutation (SNP) | VAF 141/302 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SLC26A5 | c.173G>C p.R58T | Missense Mutation (SNP) | VAF 77/222 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- SLC30A10 | c.1022T>A p.V341E | Missense Mutation (SNP) | VAF 113/316 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- SLC39A10 | c.699G>T p.R233S | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC46A2 | c.1110G>C p.E370D | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- SLC8A2 | c.2073G>C p.W691C | Missense Mutation (SNP) | VAF 101/248 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SNAP91 | c.1802C>A p.A601D | Missense Mutation (SNP) | VAF 81/286 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- SOX3 | c.1247C>G p.S416C | Missense Mutation (SNP) | VAF 73/117 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SPOUT1 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- SPTBN1 | c.4964G>C p.S1655T | Missense Mutation (SNP) | VAF 116/332 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- STON1 | c.422C>G p.S141* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- SULT1C3 | c.115G>C p.V39L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAAR8 | c.752G>C p.R251T | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TANC1 | c.3149G>T p.S1050I | Missense Mutation (SNP) | VAF 103/261 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TAS2R43 | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 96/402 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); called by muse, varscan2
- TENM2 | c.1765G>C p.G589R (on ENST00000518659 / NM_001122679.2; = p.G357R on NM_001080428.3) | Missense Mutation (SNP) | VAF 90/203 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX13C | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 118/181 reads (65%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- TMEM147 | c.361G>T p.V121F | Missense Mutation (SNP) | VAF 257/495 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- TMEM216 | c.391G>T p.E131* (on ENST00000515837 / NM_001173990.3; = p.E70* on NM_016499.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 146/426 reads (34%) | called by muse, mutect2, varscan2
- TMUB1 | c.68T>A p.V23E | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- TRIM51GP | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 83/326 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- TRIP12 | c.1520A>G p.Y507C | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TSPYL6 | c.1210C>G p.P404A | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- TTN | c.59002G>C p.D19668H (on ENST00000591111; = p.D12244H on NM_003319.4) | Missense Mutation (SNP) | VAF 145/682 reads (21%) | PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- TTN | c.8574del p.S2859Qfs*30 (on ENST00000591111; = p.S2813Qfs*30 on NM_003319.4) | Frame Shift Del (DEL) | VAF 118/405 reads (29%) | called by mutect2, pindel, varscan2
- TUBB4A | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 248/505 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- VNN1 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 73/291 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS50 | c.2331del p.K778Nfs*7 | Frame Shift Del (DEL) | VAF 42/139 reads (30%) | called by mutect2, pindel, varscan2
- VRTN | c.1814G>T p.R605I | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWA5B1 | c.3181G>T p.A1061S (on ENST00000375079; = p.A1056S on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WDFY4 | c.5501A>G p.Q1834R | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2
- WDR64 | c.2558A>T p.D853V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- WDR86 | c.954C>G p.I318M | Missense Mutation (SNP) | VAF 108/358 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- WEE2 | c.1331G>T p.R444L | Missense Mutation (SNP) | VAF 86/281 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB1 | c.752A>G p.H251R | Missense Mutation (SNP) | VAF 73/127 reads (57%) | SIFT tolerated (0.84); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- ZBTB1 | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 109/196 reads (56%) | called by muse, mutect2, varscan2
- ZMYM5 | c.1975G>T p.E659* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | called by muse, varscan2
- ZNF260 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ZNF300 | c.433T>A p.F145I | Missense Mutation (SNP) | VAF 105/202 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF41 | c.2239T>A p.Y747N | Missense Mutation (SNP) | VAF 69/121 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZNF605 | c.350G>C p.R117T | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF669 | c.278A>C p.E93A | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- ZNF679 | c.839C>A p.S280Y | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ZNF729 | c.1208C>A p.P403H | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF853 | c.1004_1011del p.L335Pfs*173 | Frame Shift Del (DEL) | VAF 79/185 reads (43%) | called by mutect2, pindel, varscan2
- ZNF90 | c.883A>T p.I295F | Missense Mutation (SNP) | VAF 98/206 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ZWINT | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- ABCA12 | c.6930A>G p.S2310= (on ENST00000272895 / NM_173076.3; = p.S1992= on NM_015657.3) | Silent (SNP) | VAF 99/320 reads (31%) | called by muse, mutect2, varscan2
- ADAMTS8 | c.270G>T p.A90= | Silent (SNP) | VAF 154/457 reads (34%) | called by muse, mutect2, varscan2
- ADGRE5 | c.1176G>A p.E392= (on ENST00000242786 / NM_078481.4; = p.E299= on NM_001784.5) | Silent (SNP) | VAF 10/14 reads (71%) | called by muse, mutect2, varscan2
- ADGRF2 | c.1095C>G p.V365= (on ENST00000296862 / NM_001368115.2; = p.V297= on NM_153839.7) | Silent (SNP) | VAF 84/232 reads (36%) | called by muse, mutect2, varscan2
- AHNAK2 | c.9267C>T p.D3089= | Silent (SNP) | VAF 14/273 reads (5%) | catalogued as COSV60915324, COSV60924663; called by muse, mutect2
- ARPC2 | c.165G>C p.V55= | Silent (SNP) | VAF 36/129 reads (28%) | called by muse, mutect2, varscan2
- ATP10D | c.2313C>G p.P771= | Silent (SNP) | VAF 70/160 reads (44%) | called by muse, mutect2, varscan2
- ATP6V1G3 | c.78G>A p.K26= | Silent (SNP) | VAF 117/346 reads (34%) | catalogued as COSV55279201; called by muse, mutect2, varscan2
- BRINP2 | c.1458G>T p.L486= | Silent (SNP) | VAF 51/164 reads (31%) | called by muse, mutect2, varscan2
- CAMKV | c.358C>A p.R120= | Silent (SNP) | VAF 152/302 reads (50%) | catalogued as rs1203352212, COSV56556084; called by muse, mutect2, varscan2
- CCDC141 | c.3783C>T p.A1261= | Silent (SNP) | VAF 120/433 reads (28%) | called by muse, mutect2, varscan2
- CDC123 | c.366G>C p.L122= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as COSV99826822; called by muse, mutect2, varscan2
- CFAP94 | c.1683C>T p.F561= (on ENST00000320267 / NM_001352064.2; = p.F567= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/143 reads (39%) | called by muse, mutect2, varscan2
- CHAT | c.1575G>A p.K525= | Silent (SNP) | VAF 151/504 reads (30%) | called by muse, mutect2, varscan2
- CNTN1 | c.2265A>G p.K755= | Silent (SNP) | VAF 98/287 reads (34%) | called by muse, mutect2, varscan2
- COL20A1 | c.1149G>T p.L383= | Silent (SNP) | VAF 36/171 reads (21%) | called by muse, mutect2, varscan2
- CRX | c.198C>G p.V66= | Silent (SNP) | VAF 171/372 reads (46%) | called by muse, mutect2, varscan2
- CSF3R | c.2277C>A p.P759= | Silent (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.6564C>T p.F2188= | Silent (SNP) | VAF 37/134 reads (28%) | called by muse, mutect2, varscan2
- ENPP2 | c.1890C>G p.L630= (on ENST00000075322 / NM_001040092.3; = p.L682= on NM_006209.5) | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs759438853; called by muse, mutect2, varscan2
- FAM47A | c.1539G>T p.R513= | Silent (SNP) | VAF 37/62 reads (60%) | called by muse, varscan2
- FAM78B | c.663G>T p.R221= | Silent (SNP) | VAF 35/97 reads (36%) | called by muse, mutect2, varscan2
- FOXI2 | c.744C>T p.F248= | Silent (SNP) | VAF 88/294 reads (30%) | catalogued as COSV59095015; called by muse, mutect2, varscan2
- GABRE | c.237G>C p.L79= | Silent (SNP) | VAF 135/197 reads (69%) | called by muse, mutect2, varscan2
- HECW2 | c.609C>T p.F203= | Silent (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2, varscan2
- HELQ | c.486A>T p.I162= | Silent (SNP) | VAF 62/119 reads (52%) | called by muse, mutect2, varscan2
- HIVEP2 | c.7059G>T p.R2353= | Silent (SNP) | VAF 62/208 reads (30%) | catalogued as rs768674108; called by muse, mutect2, varscan2
- HLA-F | c.286C>A p.R96= | Silent (SNP) | VAF 55/135 reads (41%) | called by muse, mutect2, varscan2
- HMCN1 | c.12258G>A p.K4086= | Silent (SNP) | VAF 117/355 reads (33%) | called by muse, mutect2, varscan2
- HOXA10 | c.1053G>A p.L351= | Silent (SNP) | VAF 66/116 reads (57%) | called by muse, mutect2, varscan2
- INHBC | c.972C>T p.P324= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV59005880; called by muse, mutect2, varscan2
- ITIH4 | c.2583G>A p.L861= | Silent (SNP) | VAF 108/202 reads (53%) | called by muse, mutect2, varscan2
- IZUMO2 | c.646C>A p.R216= | Silent (SNP) | VAF 114/261 reads (44%) | catalogued as rs201116550, COSV53230995; called by muse, mutect2, varscan2
- KEAP1 | c.1874G>A p.*625= | Silent (SNP) | VAF 67/142 reads (47%) | called by muse, mutect2, varscan2
- KIFAP3 | c.1572T>C p.C524= | Silent (SNP) | VAF 65/215 reads (30%) | called by muse, mutect2, varscan2
- KMT2A | c.3819A>G p.E1273= | Silent (SNP) | VAF 120/360 reads (33%) | called by muse, mutect2, varscan2
- LAPTM4B | c.880C>T p.L294= (on ENST00000445593; = p.L203= on NM_018407.6) | Silent (SNP) | VAF 136/403 reads (34%) | catalogued as rs375370028; called by muse, mutect2, varscan2
- LRRN2 | c.1081C>T p.L361= | Silent (SNP) | VAF 141/353 reads (40%) | called by muse, mutect2, varscan2
- MMP10 | c.735C>T p.L245= | Silent (SNP) | VAF 66/214 reads (31%) | catalogued as rs143430465; called by muse, mutect2, varscan2
- MSN | c.303G>C p.L101= | Silent (SNP) | VAF 142/238 reads (60%) | called by muse, mutect2, varscan2
- MYT1L | c.1524G>C p.G508= | Silent (SNP) | VAF 79/261 reads (30%) | called by muse, mutect2, varscan2
- NDRG4 | c.27T>C p.H9= (on ENST00000570248 / NM_001378344.1; = p.H41= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 165/520 reads (32%) | called by muse, mutect2, varscan2
- NLRP14 | c.1224C>T p.F408= | Silent (SNP) | VAF 203/470 reads (43%) | catalogued as rs865982262; called by muse, mutect2, varscan2
- NMBR | c.117G>A p.E39= | Silent (SNP) | VAF 183/623 reads (29%) | catalogued as rs756802169; called by muse, mutect2, varscan2
- NR0B2 | c.327G>A p.V109= | Silent (SNP) | VAF 83/291 reads (29%) | called by muse, mutect2, varscan2
- NUP214 | c.2625G>C p.L875= | Silent (SNP) | VAF 85/161 reads (53%) | called by muse, mutect2, varscan2
- OR1N1 | c.480C>T p.L160= | Silent (SNP) | VAF 92/225 reads (41%) | called by muse, mutect2, varscan2
- OR52J3 | c.93G>T p.G31= | Silent (SNP) | VAF 134/328 reads (41%) | called by muse, mutect2, varscan2
- OR8J3 | c.54T>A p.S18= | Silent (SNP) | VAF 45/153 reads (29%) | called by muse, mutect2, varscan2
- ORC1 | c.2184T>C p.R728= | Silent (SNP) | VAF 182/505 reads (36%) | called by muse, mutect2, varscan2
- P2RY12 | c.909G>A p.K303= | Silent (SNP) | VAF 8/188 reads (4%) | called by muse, mutect2
- PAN2 | c.411C>T p.L137= | Silent (SNP) | VAF 73/213 reads (34%) | catalogued as COSV57753446; called by muse, mutect2, varscan2
- PCDH15 | c.1560A>T p.T520= | Silent (SNP) | VAF 45/171 reads (26%) | called by muse, mutect2, varscan2
- PCDHGC5 | c.1698C>T p.H566= | Silent (SNP) | VAF 46/91 reads (51%) | called by muse, mutect2, varscan2
- PKHD1 | c.7158C>T p.V2386= | Silent (SNP) | VAF 93/447 reads (21%) | catalogued as rs1166219544; called by muse, mutect2, varscan2
- PRB2 | c.984A>G p.P328= | Silent (SNP) | VAF 121/359 reads (34%) | catalogued as rs778991515; called by muse, mutect2, varscan2
- PRKX | c.645C>T p.V215= | Silent (SNP) | VAF 41/90 reads (46%) | catalogued as rs1441914870; called by muse, mutect2, varscan2
- RAF1 | c.1173G>A p.R391= | Silent (SNP) | VAF 125/261 reads (48%) | catalogued as COSV52574253, COSV99312256; called by muse, mutect2, varscan2
- RBM6 | c.1974C>A p.I658= | Silent (SNP) | VAF 63/112 reads (56%) | called by muse, mutect2, varscan2
- RYR2 | c.5604C>T p.L1868= | Silent (SNP) | VAF 54/149 reads (36%) | called by muse, mutect2, varscan2
- SEC31A | c.594T>C p.L198= | Silent (SNP) | VAF 79/162 reads (49%) | called by muse, mutect2, varscan2
- SLC25A12 | c.657C>T p.F219= | Silent (SNP) | VAF 92/327 reads (28%) | catalogued as rs1325763421, COSV55532381; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC30A9 | c.759T>C p.F253= | Silent (SNP) | VAF 14/22 reads (64%) | called by muse, mutect2, varscan2
- SLITRK2 | c.1254C>A p.A418= | Silent (SNP) | VAF 39/70 reads (56%) | called by muse, mutect2, varscan2
- SOX17 | c.630C>A p.G210= | Silent (SNP) | VAF 101/284 reads (36%) | called by muse, mutect2, varscan2
- STK36 | c.1896C>T p.L632= | Silent (SNP) | VAF 75/219 reads (34%) | called by muse, mutect2, varscan2
- SYBU | c.1851C>A p.P617= (on ENST00000276646 / NM_001099754.2; = p.P616= on NM_017786.6) | Silent (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- TBC1D30 | c.1827G>C p.L609= (on ENST00000542120; = p.L446= on NM_015279.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 89/287 reads (31%) | called by muse, mutect2, varscan2
- TBRG4 | c.1092C>T p.I364= | Silent (SNP) | VAF 88/173 reads (51%) | catalogued as COSV51834533; called by muse, mutect2, varscan2
- TBX22 | c.945A>T p.T315= | Silent (SNP) | VAF 110/154 reads (71%) | catalogued as rs1300288635; called by muse, mutect2, varscan2
- TNKS | c.2709G>T p.A903= | Silent (SNP) | VAF 82/192 reads (43%) | called by muse, mutect2, varscan2
- UBE4B | c.900C>T p.A300= | Silent (SNP) | VAF 61/136 reads (45%) | called by muse, mutect2, varscan2
- UGGT1 | c.702C>T p.P234= | Silent (SNP) | VAF 70/202 reads (35%) | called by muse, mutect2, varscan2
- ZNF516 | c.60C>T p.A20= | Silent (SNP) | VAF 141/287 reads (49%) | catalogued as rs776008486; called by muse, mutect2, varscan2
- ZNF707 | c.138T>C p.A46= | Silent (SNP) | VAF 49/116 reads (42%) | called by muse, mutect2, varscan2
- ZNF729 | c.2364A>T p.V788= | Silent (SNP) | VAF 65/147 reads (44%) | called by muse, mutect2, varscan2
- AC004890.2 | n.1512G>T | RNA (SNP) | VAF 143/423 reads (34%) | catalogued as rs956828084; called by muse, mutect2, varscan2
- AC068643.2 | n.593+320G>T | Intron (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- AC084880.2 | chr12:119220864 G>C | 3'Flank (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- AC092118.1 | n.1194C>T | RNA (SNP) | VAF 38/92 reads (41%) | called by muse, mutect2, varscan2
- AC132807.2 | n.48G>T | RNA (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- AC132807.2 | n.49G>T | RNA (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- AC136759.1 | n.1215C>A | RNA (SNP) | VAF 182/627 reads (29%) | called by muse, mutect2, varscan2
- ANKRD20A5P | n.142G>T | RNA (SNP) | VAF 98/346 reads (28%) | called by muse, varscan2
- ARHGEF7 | c.823-2543G>C | Intron (SNP) | VAF 81/241 reads (34%) | called by muse, mutect2, varscan2
- C4A | chr6:32006260 G>A | 3'Flank (SNP) | VAF 77/291 reads (26%) | catalogued as rs778091486; called by muse, mutect2, varscan2
- C4orf50 | c.-173G>C | 5'UTR (SNP) | VAF 99/211 reads (47%) | called by muse, mutect2, varscan2
- CA2 | c.-48C>A | 5'UTR (SNP) | VAF 239/804 reads (30%) | catalogued as rs1474298740; called by muse, mutect2, varscan2
- CAPN3 | c.*344C>A | 3'UTR (SNP) | VAF 77/150 reads (51%) | called by muse, mutect2, varscan2
- CDH9 | c.999+192C>G | Intron (SNP) | VAF 45/175 reads (26%) | called by muse, mutect2, varscan2
- CHEK1 | chr11:125625877 G>A | 5'Flank (SNP) | VAF 134/413 reads (32%) | catalogued as rs1479304104; called by muse, mutect2, varscan2
- CICP28 | chr7:56812085 ins T | 3'Flank (INS) | VAF 87/252 reads (35%) | called by mutect2, pindel, varscan2
- CORO6 | c.-153G>C | 5'UTR (SNP) | VAF 184/277 reads (66%) | catalogued as rs753325023; called by muse, mutect2, varscan2
- DENND10P1 | n.917G>T | RNA (SNP) | VAF 265/393 reads (67%) | called by muse, mutect2, varscan2
- EDRF1 | c.1128+1464_1128+1466del | Intron (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- EFHC1 | c.*631C>A | 3'UTR (SNP) | VAF 38/127 reads (30%) | called by muse, mutect2, varscan2
- FANCA | c.1359+44G>A | Intron (SNP) | VAF 57/331 reads (17%) | called by muse, mutect2, varscan2
- FOLH1B | n.1914C>A | RNA (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- FUS | c.190+41G>A | Intron (SNP) | VAF 81/154 reads (53%) | catalogued as rs754699731; called by muse, mutect2, varscan2
- GABRG3 | c.1123-1983C>T | Intron (SNP) | VAF 114/249 reads (46%) | called by muse, mutect2, varscan2
- KIN | c.*2042C>G | 3'UTR (SNP) | VAF 80/251 reads (32%) | called by muse, mutect2, varscan2
- LBHD1 | c.616+1151C>G | Intron (SNP) | VAF 113/385 reads (29%) | called by muse, mutect2, varscan2
- LILRB1 | c.1510+10C>G | Intron (SNP) | VAF 105/224 reads (47%) | called by muse, mutect2, varscan2
- MAST2 | c.500+31421G>C | Intron (SNP) | VAF 9/30 reads (30%) | catalogued as rs944009796; called by muse, mutect2
- MDGA2 | c.281-41503A>C | Intron (SNP) | VAF 65/141 reads (46%) | called by muse, mutect2, varscan2
- METTL24 | c.787-7674C>G | Intron (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- MYH16 | n.3370C>A | RNA (SNP) | VAF 72/239 reads (30%) | called by muse, mutect2, varscan2
- NOD2 | c.73+40C>T | Intron (SNP) | VAF 63/428 reads (15%) | catalogued as rs765461614; called by muse, mutect2, varscan2
- OAS1 | c.1038+56G>C | Intron (SNP) | VAF 97/281 reads (35%) | called by muse, mutect2, varscan2
- PINK1 | c.*49G>T | 3'UTR (SNP) | VAF 71/132 reads (54%) | called by muse, mutect2, varscan2
- PRMT3 | c.28+117C>G | Intron (SNP) | VAF 64/279 reads (23%) | called by muse, mutect2, varscan2
- PRR34 | n.326G>C | RNA (SNP) | VAF 77/262 reads (29%) | catalogued as rs768072686, COSV61549124, COSV61549256; called by muse, mutect2, varscan2
- PRRC2A | c.112+290G>C | Intron (SNP) | VAF 96/305 reads (31%) | called by muse, mutect2, varscan2
- PTPRC | c.-40G>A | 5'UTR (SNP) | VAF 86/262 reads (33%) | catalogued as rs756237254; called by muse, mutect2, varscan2
- RNF31 | c.495+47G>A | Intron (SNP) | VAF 88/187 reads (47%) | catalogued as rs778482769, COSV53758541, COSV99396221; called by muse, mutect2, varscan2
- SLC25A51P4 | n.921C>A | RNA (SNP) | VAF 36/181 reads (20%) | called by muse, mutect2, varscan2
- SLC37A2 | c.1490+212G>C | Intron (SNP) | VAF 67/246 reads (27%) | called by muse, mutect2, varscan2
- SSPOP | n.8323A>C | RNA (SNP) | VAF 35/111 reads (32%) | called by muse, mutect2, varscan2
- SUN1 | c.658+78C>G | Intron (SNP) | VAF 44/121 reads (36%) | called by muse, mutect2, varscan2
- TAAR3P | n.889C>A | RNA (SNP) | VAF 56/162 reads (35%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*1154G>C | 3'UTR (SNP) | VAF 101/225 reads (45%) | called by muse, mutect2, varscan2
- TSBP1-AS1 | n.339C>G | RNA (SNP) | VAF 60/196 reads (31%) | called by muse, mutect2, varscan2
- TUBB8 | c.-16del | 5'UTR (DEL) | VAF 60/190 reads (32%) | called by mutect2, pindel, varscan2
- ZNF26 | c.34-5361G>T | Intron (SNP) | VAF 105/377 reads (28%) | called by muse, mutect2, varscan2
- ZNF569 | c.-3G>A | 5'UTR (SNP) | VAF 31/155 reads (20%) | called by muse, mutect2, varscan2
